Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N4, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N4-01A (Primary Tumor).

[page 1 of 2]
HISTOPATHOLOGY REPORT

REQUEST DETAILS

Porto-caval lymph node, ? metastatic adenocarcinoma. Frozen section.

Distal gastrectomy, adenocarcinoma. Specimen histology.

MACROSCOPIC DESCRIPTION

1. Specimen labelled porto-caval lymph node. Received fresh for frozen section is a lymph node 15 x 12 x 10mm with a pale firm cut surface. 1.1 frozen section block, 1.2 two further representative cross sections.
2. Specimen labelled gastrectomy. Received fresh for tissue bank is a distal gastrectomy stapled at proximal and distal ends. It is 110mm along the lesser curve and 150mm along the greater curve with stapled margins 90mm and 25mm at proximal and distal ends respectively. Opening of the specimen along the greater curve reveals a circumferential induration of the pylorus. The surface mucosa is granular and finely nodular and the underlying wall shows diffuse thickening up to 12mm in thickness. The tumour is very poorly circumscribed with the area of mural thickening tapering as the tumour spreads proximally into the stomach. The duodenal margin is approximately 20mm and no macroscopic tumour is identified involving that. There is no ulceration. Gastric mucosa more proximally is finely granular and shows no other special features. Only a very small amount of lesser omental fat is present and there is only one probable lymph node identified. A larger quantity of greater omental fat is present and this contains multiple firm lymph nodes up to 10mm. Blocks 2.1 proximal and distal resection margins, 2.2 LS tumour lesser curve, 2.3, 2.4 TS pylorus, 2.5 lesser curve proximal to tumour, 2.6 proximal greater curve, 2.7 lesser omentum including one probable lymph node, 2.8, 2.9 greater curve lymph nodes.

FROZEN SECTION OPINION:

Report by _____ to
adenocarcinoma. Report to _____

: Metastatic

ICD O 3
Adenocarcinoma, diffuse
08/45/3
Site: Gastric antrum
C16.3
W 3/28/14

MICROSCOPIC DESCRIPTION

1. Sections of lymph node show extensive replacement by poorly differentiated adenocarcinoma. The tumour is present in sheets and comprises large pleomorphic tumour cells with somewhat eccentric irregular hyperchromatic nuclei and frequent mitoses. Scattered cells contain intracytoplasmic mucin vacuoles.
2. Sections show a poorly differentiated adenocarcinoma, diffuse type, of distal stomach which extends through the full thickness of the gastric wall to infiltrate adjacent lesser and greater omentum and extend to the serosal surface. The tumour extends distally into the duodenum in submucosa, muscle and serosal layers, with serosal tumour being seen very close to the distal resection margin (the actual margin cannot be sampled because of staples). Proximally, the tumour extends predominantly in the submucosa. Precise size of the tumour is difficult to estimate but it would appear to be at least 40mm. Overlying mucosa appears relatively intact with a marked chronic gastritis displaying mild activity. Helicobacter are not identified. There is no intestinal metaplasia. Proximal resection margin appears well clear of tumour. One lesser curve lymph node and two of seven greater curve lymph nodes show involvement by metastatic carcinoma.

DIAGNOSIS

1. Porto-caval lymph node - metastatic adenocarcinoma.
2. Distal gastrectomy - poorly differentiated adenocarcinoma,

[page 2 of 2]
diffuse type, of distal stomach, approximately 40mm maximal dimension, extending close to the distal margin, to serosa and into lesser and greater omentum, three of seven regional lymph node involved.

(Specimen Collected:

Source: NCI Genomic Data Commons file f57c0f15-ccbd-41ce-9d1c-245a3116392d (TCGA-RD-A8N4.12BB6115-383B-40FB-A4AD-9C7BFD95F8F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).